Somatic mutation profile of tumor specimen ALCH-B2S0-TTP1-A (aliquot ALCH-B2S0-TTP1-A-8-0-D-A77K-36) from ALCHEMIST case ALCH-B2S0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.3 years (18,729 days).
Specimen ALCH-B2S0-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59864ff0-b995-4cf3-8831-df66ddd2a21d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2S0-NB1-A (Blood Derived Normal), aliquot ALCH-B2S0-NB1-A-1-0-D-A77K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9069e5d-aec2-4e9e-994f-36427f8c4327

The open-access MAF lists 36 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Intron 5, Silent 5, Nonsense Mutation 2, Splice Site 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 8/66 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CRTAC1 | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100085740; called by muse, mutect2
- DNAH8 | c.2788C>T p.R930C | Missense Mutation (SNP) | VAF 19/245 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.513); catalogued as rs777860401; called by muse, mutect2
- GUCY1A2 | c.2002C>T p.R668* | Nonsense Mutation (SNP) | VAF 13/116 reads (11%) | catalogued as rs529839329, COSV56477145; called by muse, mutect2, varscan2
- ICE2 | c.1670G>T p.G557V | Missense Mutation (SNP) | VAF 40/329 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs757162829; called by muse, mutect2, varscan2
- MYO3A | c.4192A>G p.T1398A | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); catalogued as rs1564621326; called by muse, mutect2
- PCDHGA5 | c.861A>C p.K287N | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as rs1263019810; called by muse, mutect2
- SALL2 | c.23A>C p.K8T | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as rs1276957722; called by muse, mutect2
- TLR8 | c.2395G>T p.V799L (on ENST00000218032 / NM_138636.5; = p.V817L on NM_016610.4) | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as rs369919085; called by muse, mutect2, varscan2
- TRPM8 | c.2956G>A p.V986I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.972); catalogued as rs148556306; called by muse, mutect2
- CATSPERE | c.2702+1G>A p.X901_splice | Splice Site (SNP) | VAF 27/188 reads (14%) | called by muse, mutect2, varscan2
- CERS1 | c.212C>A p.T71N | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CTC1 | c.2227A>G p.K743E | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.225); called by muse, mutect2
- F5 | c.4498G>T p.D1500Y | Missense Mutation (SNP) | VAF 54/598 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.635); called by muse, mutect2
- HCN1 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, varscan2
- HGD | c.636C>G p.D212E | Missense Mutation (SNP) | VAF 58/371 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HILPDA | c.92T>A p.L31Q | Missense Mutation (SNP) | VAF 32/268 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- ICE2 | c.1669G>T p.G557* | Nonsense Mutation (SNP) | VAF 38/327 reads (12%) | called by muse, mutect2, varscan2
- IGHV1-18 | c.119C>A p.S40Y | Missense Mutation (SNP) | VAF 34/366 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IL20RB | c.323C>A p.P108Q | Missense Mutation (SNP) | VAF 4/88 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.522); called by muse, mutect2
- MAN2B2 | c.2663G>A p.S888N | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- MAP1B | c.1354A>T p.I452F | Missense Mutation (SNP) | VAF 9/265 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2
- RNF213 | c.13706C>T p.T4569I | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TDRD6 | c.2535G>T p.E845D | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.058); called by muse, mutect2
- APOOL | c.348A>G p.G116= | Silent (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
- CCDC168 | c.12543A>G p.A4181= | Silent (SNP) | VAF 14/256 reads (5%) | called by muse, mutect2
- OR2J2 | c.681G>T p.L227= | Silent (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2
- SLC30A3 | c.1107C>T p.V369= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs764446360; called by muse, mutect2, varscan2
- TTC23L | c.208T>C p.L70= | Silent (SNP) | VAF 20/134 reads (15%) | called by muse, mutect2
- ANKRD13D | c.*1060G>A | 3'UTR (SNP) | VAF 10/110 reads (9%) | catalogued as rs78983123, COSV57384854; called by muse, mutect2
- CCT3 | c.31+1001A>G | Intron (SNP) | VAF 7/59 reads (12%) | catalogued as rs1291738365; called by muse, mutect2
- ENGASE | c.1039-321C>T | Intron (SNP) | VAF 13/132 reads (10%) | catalogued as rs188583347; called by muse, mutect2
- FBXL18 | c.2000+1273T>G | Intron (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- FRMD4A | c.1117+154C>T | Intron (SNP) | VAF 53/215 reads (25%) | catalogued as rs773490881, COSV52726262; called by muse, mutect2, varscan2
- NAMPTP1 | n.1259A>C | RNA (SNP) | VAF 20/393 reads (5%) | called by muse, mutect2
- RPL24 | c.393+24_393+34del | Intron (DEL) | VAF 27/139 reads (19%) | called by mutect2, pindel, varscan2
